Surgical pathology report (de-identified scan), TCGA case TCGA-DX-AB2G, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-AB2G-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

ICD.O-3
Liposarcoma, dedifferentiated
8858/3
Site Retroperitoneum
C480
JAS/10/14

Specimens Submitted:

- 1: Omentum (mass); excision
- 2: Right kidney, right adrenal, and soft tissue mass; radical resection

DIAGNOSIS:

1. Omentum (mass); excision:
- Mature adipose tissue without overt atypia (4.0 x 2.6 x 1.3 cm).
2. Right kidney, right adrenal, and soft tissue mass; radical resection:
- Dedifferentiated liposarcoma arising in a background of well-differentiated liposarcoma.
- Tumor sizes (two masses): 36.0 x 30.0 x 14.5 cm and 4.0 cm.
- The dedifferentiated component comprises 30% of the tumor and has a malignant fibrous histiocytoma-like morphology.
- The tumor encases the kidney and adrenal gland.
- The tumor shows areas of necrosis, fibrosis and calcification (20% of tumor).
- The tumor is covered by a thin fibrous membrane which represents the surgical margin.
- Ureter and renal vascular margins are uninvolved by tumor.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

- 1) The specimen is received fresh, labeled "Omental mass". It consists of a

** Continued on next page **

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 2
9.5 x 5.1 x 1.5 cm aggregate of adipose tissue consistent with omentum. Serial sectioning reveals 4.0 x 2.6 x 1.3 cm tan lipomatous mass with a homogenous cut surface. Representative sections of the mass and the uninvolved omental tissue are submitted.

Summary of sections:

M - mass
O - omentum

2) The specimen is received fresh, labeled "Radical resection of right kidney, right adrenal and liposarcoma". It consists of a 36.0 x 30.0 x 14.5 cm tan-yellow mass. The external surface is mostly covered by a thin smooth membrane. It is inked black and the specimen is sectioned revealing solid multi-lobulated cut surfaces with tan yellow lipomatous areas and focal tan-fleshy areas. The tumor is encasing the kidney (11.0 x 6.0 x 5.0 cm, with attached ureter: 18.0 cm in length x 0.4 cm in diameter), but does not appear to invade into it grossly. Also attached to the mass is the adrenal gland (6.0 x 2.0 x 1.5 cm), with an adjacent separate tan-yellow solid tumor with a homogenous lipomatous cut surface measuring 4.0 cm in greatest dimensions. The main tumor shows areas of necrosis and myxoid change (with rare foci of calcifications), approximately 20% of the tumor. The specimen is representatively submitted. Photographs and tissue for TPS are taken.

Summary of sections:

T main tumor
K kidney with tumor
AD adrenal gland with tumor
T2 tumor adjacent to adrenal gland
VUM renal vascular and ureter margins

Summary of Sections:

Part 1: Omentum (mass); excision

Blocks	Block Designation	PCs
4 M	4	
1 O	2	

Part 2: Right kidney, right adrenal, and soft tissue mass; radical resection

Blocks	Block Designation	PCs
2 AD	2	
2 K	2	
10 T	20	
2 T2	2	
1 VUM	4	

** End of Report **

Source: NCI Genomic Data Commons file 82123f15-fce4-4e5a-b27a-c54c8a1aff0b (TCGA-DX-AB2G.B3219517-F945-4EF3-987B-832EDC79D848.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).